Surgical pathology report (de-identified scan), TCGA case TCGA-KM-A7QJ, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-A7QJ-01C (Primary Tumor).

[page 1 of 3]
MEDICAL RECORD

Revised Surgical Pathology Report

Revised Surgical Pathology Report

PATIENT:	MRN:
ACCOUNT#:	RECEIVED DATE:
DOB:	PROCEDURE DATE:
AGE:	SIGN-OUT DATE:
ATTENDING:	LOCATION:
REQUESTING:	ROOM:
CONTACT NO:	
COPIES TO:	

SEX: M

REVISED REPORT

REASON FOR REVISION: A computer software error caused corruption in the original final report. This incomplete, corrupted report was signed out so that a clean revised report could be created. This revised report therefore represents the true original final report.

DIAGNOSIS: Kidney, right (radical nephrectomy): Renal cell carcinoma, chromophobe type, Fuhrman nuclear grade 2, vascular and ureteral margins are free of tumor. Tumor does not involve the capsule, see Note.

NOTE:
Kidney Nephrectomy Summary Table Macroscopic

Specimen Type: Radical nephrectomy.
Laterality: Right

Tumor Size: 4.0 cm
Focality: unifocal

Macro Extent of Tumor: Tumor limited to kidney

Microscopic

Histologic Type: Chromophobe
Histologic Grade: G2

Extent of Invasion
Primary Tumor(pT): PT1a
Regional Lymph Nodes(pN): pNx
Distant Metastasis(pM): pNx
Margins: Uninvolved by invasive carcinoma

ICD-O-3
Carcinoma, renal cell chromophobe
type
Site @ Kidney NOS 8317/3
C64.9
JAW 9/24/13

Patient Identification

[page 2 of 3]
MEDICAL RECORD	Revised Surgical Pathology Report
-----------------------	--

Name:

MRN:

Date of Report:

CLINICAL INFORMATION: Brief Clinical History: right renal mass Specimen Taken For Protocol:

Requestor Name
Admitting Protocol Number:

Requestor Phone/Pager:

PROCEDURE: Pre-Operative Diagnosis: right renal mass Post-Operative Diagnosis:
right renal mass Operative Findings: right renal mass

SPECIMENS SUBMITTED: 1. KIDNEY, RIGHT

GROSS DESCRIPTION: Received from the OR labeled with the patient's name, medical record and "right kidney" is a radical nephrectomy specimen measuring over all 17.0 x 10.0 x 6.0 cm and weighing 550 gm, containing the Gerota's fascia (kidney is measuring 7.0 x 6.0 x 3.5 cm). The ureter, renal artery, renal vein are identified (ureter measuring 10.0 cm in length by 0.5 cm in diameter, renal artery measuring 1.5 cm in length by 0.4 cm in diameter, renal vein measuring 1.5 cm in length by 0.8 cm in diameter). The specimen is inked in black and bivalved to reveal a nodule measuring 3.0 x 3.5 x 4.0 cm with variegated gray/brown cut surface, confined in the lower pole of the kidney. The remaining of the kidney appears normal (cortical thickness is 1.2 cm, medulla thickness is 1.7 cm). Approximately 1.5 x 1.5 cm of the tumor tissue and two slices of normal kidney parenchyma (each measuring 1.2 x 4.0 x 4.0 cm) were procured for by and on

The remaining specimen is sent to Surgical Pathology. In Surgical Pathology is received in filled container and is consistent with above description. It is sectioned for further examination. Adrenal gland is not identified. Lymph nodes are grossly not identified. Representative section is submitted in white cassette labeled and further described as follows:

- A. Resection margin (ureter, renal artery, renal vein).
- B-D. Tumor mass
- E-F. Perirenal fat, lymph nodes?
- G. Normal appearing kidney
- H-P. Tumor mass

Patient Identification

[page 3 of 3]
MEDICAL RECORD

Revised Clinical Pathology Report

Date of Report:

Criteria	W 9/13/13	Yes	No
Prior Malignancy History	bladder - M TX	✓	
Dual/Synchronous Primary	Noted	✓	

Patient Identification

Source: NCI Genomic Data Commons file c5b8f7b9-8d33-451e-b249-1019531c9528 (TCGA-KM-A7QJ.8A26F1CA-2DD1-46FD-B2A7-FEFDF3811455.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).